Surgical pathology report (de-identified scan), TCGA case TCGA-28-2506, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2506-01A (Primary Tumor).

TCGA-28-2506

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

- A. BRAIN, RIGHT PARIETAL, CORE BIOPSY:
- Glioblastoma multiforme, WHO grade IV
- B. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #1:
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 80% of tumor cellularity
- C. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #2:
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity
- D. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #3:
- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 80% of tumor cellularity
- E. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #4:
- Glioblastoma multiforme, WHO grade IV
- 3% of tumor necrosis
- 90% of tumor cellularity
- F. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY, NCI #5:
- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 95% of tumor cellularity
- G. BRAIN, RIGHT PARIETAL, EXCISIONAL BIOPSY:
- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Source: NCI Genomic Data Commons file a0c4b9e3-39fe-4939-ac40-6ef326b71e53 (TCGA-28-2506.56A90981-A40F-463D-902C-1524037DF000.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).